Gene-level copy-number profile of specimen HCM-SANG-0306-C15-85A from HCMI case HCM-SANG-0306-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0306-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 70d96206-3b91-4cab-a618-9c6e5611b8a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0306-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/b4c5cc01-7980-45ee-ada2-0ab47b8f6c4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,056; copy number 2: 28,481; copy number 3: 22,877; copy number 4: 461; copy number 5: 1,715; copy number 6: 661; copy number 7: 111.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:8,981,436–8,990,806, 2 genes: AC073648.3, AC073648.2.
- chr11:4,242,056–4,242,640, 1 gene: SSU72P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,483 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:233,307,816–233,586,291, 7 genes, copy number 7: SAG, AC013726.1, DGKD, Y_RNA, USP40, PPFIA1P1, UGT1A12P.
- chr5:58,198–54,415,238, 733 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:55,602,360–55,666,195, 4 genes, copy number 6: OR4C11, OR4P4, OR4S2, OR4C6.
- chr17:15,732,247–19,868,689, 235 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr17:20,321,164–21,704,612, 82 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr18:21,704,957–22,419,294, 25 genes, copy number 6–7: MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr20:87,250–16,053,197, 286 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 5 (within-gene range 3–5): MACROD2-AS1.
- chr20:15,280,764–64,327,972, 1,110 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,885. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
